Somatic mutation profile of tumor specimen MMRF_1235_1_BM_CD138pos (aliquot MMRF_1235_1_BM_CD138pos_T2_KAS5U_L02448) from MMRF case MMRF_1235, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,497 days).
Specimen MMRF_1235_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 055224c9-6702-4104-891d-a573c8b3f877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1235_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1235_2_PB_WBC_C3_KBS5U_L05823; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cff67d79-1fe1-418b-be72-74e0c598e468

The open-access MAF lists 84 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 18, Intron 11, Silent 8, 5'UTR 6, RNA 2, Splice Site 2, In Frame Del 2, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/190 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLI2 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 176/355 reads (50%) | catalogued as rs876661324, COSV58053465; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748063552; called by muse, mutect2, varscan2
- ALG10B | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV58143291; called by muse, mutect2, varscan2
- AP1AR | c.159+4_159+7del p.X53_splice | Splice Site (DEL) | VAF 27/56 reads (48%) | catalogued as rs751962437; called by pindel, varscan2
- ARIH2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs753506586, COSV62703728, COSV62706358; called by muse, mutect2, varscan2
- CSMD1 | c.5384C>T p.T1795M (on ENST00000520002; = p.T1794M on NM_033225.6) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1319317481; called by muse, mutect2, varscan2
- FKBP15 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99439491; called by muse, mutect2, varscan2
- GFRAL | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs534778776; called by muse, mutect2, varscan2
- IGHV2-70D | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1319867197; called by muse, mutect2, varscan2
- IGKV1-27 | c.157A>G p.N53D | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs757117470; called by muse, varscan2
- LEMD2 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs147300954; called by muse, mutect2, varscan2
- MED4 | c.682T>G p.S228A | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51640650; called by muse, mutect2, varscan2
- NAA60 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs761553965; called by muse, mutect2, varscan2
- PARN | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs754540436, COSV58368835; called by muse, mutect2, varscan2
- PDK3 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 39/39 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1356075616, COSV64792730; called by muse, mutect2, varscan2
- ADGRG1 | c.1931G>T p.S644I | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CCN3 | c.1007A>C p.N336T | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAM117A | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FICD | c.614T>A p.V205D | Missense Mutation (SNP) | VAF 284/652 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- FUT3 | c.919_951del p.Q307_L317del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- GTF2A2 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HESX1 | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- IGHA1 | c.668-1G>A p.X223_splice | Splice Site (SNP) | VAF 18/21 reads (86%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.18); PolyPhen benign (0.432); called by mutect2, varscan2
- IGKV1-27 | c.289A>T p.I97F | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, varscan2
- INTU | c.2240A>G p.D747G | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC9 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL17 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2K6 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRGPRX4 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8J1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 92/176 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PACC1 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PEX10 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RB1 | c.2118_2120del p.S707del | In Frame Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- SMARCA2 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- THEMIS | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZFHX3 | c.6527_6528del p.K2176Rfs*28 | Frame Shift Del (DEL) | VAF 67/96 reads (70%) | called by mutect2, pindel, varscan2
- ACSM1 | c.1266T>A p.P422= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3507C>T p.F1169= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs777912167, COSV60096720; called by muse, mutect2, varscan2
- ANKEF1 | c.2166A>C p.P722= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- ASXL3 | c.3414G>T p.G1138= | Silent (SNP) | VAF 104/211 reads (49%) | catalogued as COSV52481645; called by muse, mutect2, varscan2
- DDX49 | c.27G>A p.L9= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1311756589; called by muse, mutect2, varscan2
- IL20RA | c.1335G>A p.T445= | Silent (SNP) | VAF 92/180 reads (51%) | catalogued as rs562574600; called by muse, mutect2, varscan2
- PCDHB14 | c.531C>T p.H177= | Silent (SNP) | VAF 139/284 reads (49%) | called by muse, mutect2, varscan2
- ZFHX4 | c.576C>T p.I192= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as rs1263475233, COSV51455926, COSV99262351; called by muse, mutect2, varscan2
- ABCC8 | c.*90G>T | 3'UTR (SNP) | VAF 92/200 reads (46%) | called by muse, mutect2, varscan2
- BNIP1 | c.490+1325G>C | Intron (SNP) | VAF 68/158 reads (43%) | called by muse, mutect2, varscan2
- C3orf22 | c.*9C>A | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- CEP19 | c.*84A>G | 3'UTR (SNP) | VAF 83/155 reads (54%) | called by muse, mutect2, varscan2
- DNMT3A | c.448+262_448+296del | Intron (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel
- DPYSL3 | c.*857G>A | 3'UTR (SNP) | VAF 45/108 reads (42%) | catalogued as rs935005426; called by muse, mutect2, varscan2
- ELP1 | c.3856-857G>A | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- EPB41L3 | c.-11-31T>A | Intron (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- FBXO9 | c.*84G>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | catalogued as rs1478086821; called by muse, varscan2
- FGF7 | c.286+684A>G | Intron (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- FGFR3 | c.*462G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs1388464798, COSV53396258; called by muse, mutect2, varscan2
- FGR | c.226+173C>T | Intron (SNP) | VAF 77/82 reads (94%) | called by muse, mutect2, varscan2
- FLNB | c.*867C>T | 3'UTR (SNP) | VAF 81/173 reads (47%) | called by muse, mutect2, varscan2
- GLYATL2 | c.*289A>C | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- GNPTAB | c.771+1613A>C | Intron (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- GPRC5A | c.982-56C>G | Intron (SNP) | VAF 134/277 reads (48%) | called by muse, mutect2, varscan2
- GTF2H1 | c.1053+94C>T | Intron (SNP) | VAF 15/427 reads (4%) | called by muse, mutect2
- KBTBD2 | c.-273T>G | 5'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- KLHL4 | c.*3257C>A | 3'UTR (SNP) | VAF 18/18 reads (100%) | called by muse, mutect2, varscan2
- LINC01460 | n.1312_1326del | RNA (DEL) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- MNS1 | c.*113G>A | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- MYO1E | c.-92C>T | 5'UTR (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- NOG | c.-448C>A | 5'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.*91G>A | 3'UTR (SNP) | VAF 74/210 reads (35%) | called by muse, mutect2
- PABPC4L | c.-127T>G | 5'UTR (SNP) | VAF 45/84 reads (54%) | catalogued as rs1277930809; called by muse, mutect2, varscan2
- PARG | c.*950G>T | 3'UTR (SNP) | VAF 32/37 reads (86%) | called by muse, mutect2, varscan2
- PAWR | c.*1016C>T | 3'UTR (SNP) | VAF 48/88 reads (55%) | called by muse, mutect2, varscan2
- PCDH7 | chr4:30720294 del GAGGA | 5'Flank (DEL) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- PCDHB13 | c.-194A>C | 5'UTR (SNP) | VAF 89/196 reads (45%) | called by muse, mutect2, varscan2
- PHC1P1 | n.502C>G | RNA (SNP) | VAF 112/198 reads (57%) | called by muse, mutect2, varscan2
- PLOD2 | c.1128-454G>T | Intron (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- PSMB9 | c.-11G>A | 5'UTR (SNP) | VAF 6/30 reads (20%) | catalogued as rs749253062; called by muse, mutect2, varscan2
- SLC12A1 | c.1215+1996A>C | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*8434G>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- TRAF3IP2 | c.*182G>T | 3'UTR (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- TSPAN18 | c.*684A>C | 3'UTR (SNP) | VAF 95/243 reads (39%) | called by muse, mutect2, varscan2
- ZNF235 | c.*56G>T | 3'UTR (SNP) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- ZNF462 | c.*1880G>A | 3'UTR (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
